Gene-level copy-number profile of specimen HCM-BROD-0194-C15-85B from HCMI case HCM-BROD-0194-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 47.8 years (17,477 days).
Specimen HCM-BROD-0194-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ba0e3355-8a04-458e-bc6d-7a32be97e052.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0194-C15-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/74052479-e429-4a10-9e5d-948a0f7601cf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 74; copy number 1: 1,000; copy number 2: 17,335; copy number 3: 25,411; copy number 4: 12,651; copy number 5: 1,077; copy number 6: 540; copy number 7: 301; copy number 8: 27; copy number 9: 152; copy number 10: 69; copy number 12: 13; copy number 14: 38; copy number 15: 8; copy number 16: 17; copy number 17: 9; copy number 19: 28; copy number 21: 23; copy number 22: 65; copy number 25: 12; copy number 33: 8; copy number 37: 1; copy number 41: 52.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–3,057,959, 25 genes (within-gene range 0–7): LINC01986, AC066595.1, CHL1-AS2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144, CNTN4, CNTN4-AS2, AC087427.1, HINT2P1, DNAJC19P4.
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–2): AC104164.2, MIR548BB.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr8:3,373,353–3,375,226, 1 gene (within-gene range 0–1): AC026991.1.
- chr8:3,700,492–3,700,628, 1 gene (within-gene range 0–1): RNA5SP251.
- chr8:8,228,595–8,244,865, 2 genes: FAM86B3P, ALG1L13P.
- chr11:49,915,013–50,422,316, 18 genes: OR4A49P, OR4A18P, OR4A19P, OR4R3P, OR4C13, OR4C12, OR4C45, OR4C49P, GTF2IP11, AC109635.3, AC109635.6, PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 811 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,652,050–143,846,504, 12 genes, copy number 8: RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2.
- chr3:3,039,033–6,365,885, 35 genes, copy number 7 (within-gene range 0–7): CNTN4-AS1, IL5RA, AC024060.1, TRNT1, CRBN, AC024060.2, AC034195.1, SUMF1, LRRN1, AC023480.1, PNPT1P1, AC023483.1, SETMAR, MRPS10P2, ITPR1-DT, ITPR1, EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40, RNF10P1, UBTFL8, Y_RNA, AC090955.1, ARL8B, AC026202.2, AC026202.3, EDEM1, MIR4790, RN7SL553P, AC026202.1, AC087857.1, AC026167.1, AC027119.1.
- chr3:86,876,388–87,276,584, 6 genes, copy number 8: VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1.
- chr7:53,862,233–56,063,989, 51 genes, copy number 15–33: HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15.
- chr8:6,406,596–6,648,508, 1 gene, copy number 17 (within-gene range 5–17): MCPH1.
- chr8:6,499,632–7,355,359, 47 genes, copy number 12–22: ANGPT2, AC018398.2, AF287957.1, MCPH1-AS1, MIR8055, AGPAT5, MIR4659A, MIR4659B, XKR5, GS1-24F4.2, DEFB1, RPL23AP96, DEFA6, AF233439.1, DEFA4, DEFA8P, DEFA9P, DEFA10P, DEFA1, DEFT1P, DEFA1B, DEFT1P2, DEFA3, DEFA11P, DEFA7P, DEFA5, AF238378.1, AF228730.5, AF228730.2, RPS3AP30, SNRPCP6, SNRPCP15, RPS3AP33, AF228730.1, AF228730.3, OR7E125P, FAM90A15P, FAM90A3P, FAM90A4P, FAM90A13P, FAM90A5P, FAM90A20P, FAM66B, DEFB109B, USP17L1, USP17L4, AC130360.1.
- chr8:8,317,736–10,847,594, 60 genes, copy number 7–10: PRAG1, AC103957.1, AC103957.2, AC114550.2, AC114550.3, AC114550.1, RN7SL178P, CLDN23, AC087269.1, MFHAS1, RNU6-682P, AC087763.1, RPL10P19, SNORA70, ERI1, MIR4660, RNU7-55P, Metazoa_SRP, PPP1R3B, AC022784.5, AC022784.1, AC022784.6, AC022784.2, AC022784.4, AC022784.3, RNU6-1151P, AC021736.1, AC021242.2, RNU6-526P, AC021242.1, AC021242.3, TNKS, AC103834.1, MIR597, MIR124-1HG, MIR124-1, AC034111.2, AC034111.1, MSRA, AC023385.1, AC079200.1, AC112673.1, AC104964.2, LINCR-0001, PRSS52P, RNU6-729P, AC104964.1, PRSS51, AC104964.3, PRSS55, RP1L1, MIR4286, C8orf74, RNA5SP252, SOX7, AC105001.2, AC105001.1, PINX1, MIR1322, AC011008.1.
- chr8:11,486,894–12,333,693, 38 genes, copy number 14: BLK, AC022239.1, LINC00208, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P, DEFB136, DEFB135, DEFB134, AC107918.3, DEFB131E, AC107918.2, AC107918.1, DEFB131C, DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P, FAM86B1, AC145124.1, ENPP7P12, DEFB131D, DEFB130A, RNA5SP254.
- chr8:12,628,476–13,604,610, 18 genes, copy number 10 (within-gene range 4–10): RPS3AP35, AC068587.3, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA.
- chr8:13,844,101–18,401,218, 62 genes, copy number 9 (broad region; genes not listed).
- chr8:19,084,992–19,259,469, 2 genes, copy number 9 (within-gene range 2–9): AC100849.1, AC100849.2.
- chr8:19,817,391–20,303,963, 10 genes, copy number 9: INTS10, LPL, AC100802.1, RPL30P9, SLC18A1, ATP6V1B2, RNU6-892P, LZTS1, LZTS1-AS1, RNA5SP257.
- chr8:31,639,222–37,331,991, 62 genes, copy number 9 (within-gene range 9–12) (broad region; genes not listed).
- chr12:23,529,504–29,381,189, 107 genes, copy number 9–41 (broad region; genes not listed).
- chr12:64,759,496–64,977,509, 1 gene, copy number 16 (within-gene range 3–16): AC078815.1.
- chr12:64,883,394–67,096,410, 41 genes, copy number 9–19 (within-gene range 5–19): LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1.
- chr18:15,159,724–15,330,282, 6 genes, copy number 7: AP005901.2, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr19:24,146,701–24,163,425, 2 genes, copy number 7: AC073534.2, AC073534.1.
- chr20:20,052,514–20,360,703, 1 gene, copy number 7 (within-gene range 2–9): CFAP61.
- chr20:20,214,299–23,190,419, 63 genes, copy number 7 (within-gene range 7–9) (broad region; genes not listed).
- chr20:42,072,752–49,036,693, 186 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 281. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
